CCDI case PBCBXJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/4b13e80b-2057-46c0-ad76-794fc063a2ac

Demographics
Sex at birth: male.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Prostate gland; Age at diagnosis: 17.3 years (6,308 days).

Biospecimens (3 samples)
- Sample 0DQ55B: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ55L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ55S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
